Surgical pathology report (de-identified scan), TCGA case TCGA-AN-A0XW, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Cureline, specimen TCGA-AN-A0XW-01A (Primary Tumor).

TSS Patient ID:

Case #: DOB: Sex: Female Ethnicity (Race):

Cancer Sample

Diagnosis: **Breast Cancer** Histological description: **Infiltrative ductal carcinoma**

Date of Procurement Anatomic Site: **Left Breast** Tumor location: **Primary**

Tissue Specification: **Tumor** Specimen Matrix: **Tissue** Specimen Format: **OCT**

Container: **block** Type of Procurement: **surgery** Grade: **2**

T Stage: **2** N Stage: **1** M Stage: **0** Treatment: **none**

Treatment Details: **n/a**

Normal Sample

Anatomic Site: **Blood** Sample Type: **Normal** Type of Procurement: **blood draw**

Matrix: **Blood** Specimen Format: **frozen** Container: **tube**

Date of Procurement:

ICD-0-3

carcinoma, infiltrating duct, NOS 8500/3

Site: breast, NOS C50.9 lw 10/21/11

Primary Malignancy History		☒

Source: NCI Genomic Data Commons file 7edb22d8-93ff-461f-8277-294ecad6a156 (TCGA-AN-A0XW.5CBC6417-4E3D-4E9C-AE93-A56B777EF2F4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).